Surgical pathology report (de-identified scan), TCGA case TCGA-XU-AAXZ, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-AAXZ-01A (Primary Tumor).

[page 1 of 2]
IGD-0-3
Thymoma, type B3
malignant 8585/3
Site: Thymus C379
JW 5/21/14

Patient Name:
MRN: Service: Collected:
DOB: (Age: Visit #: Resulted:
Gender:M Location:
Facility:
Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: thymus gland and thymoma, stitch marks L pleura

DIAGNOSIS

Thymectomy:

- Thymoma, WHO type B3 with squamous differentiation. (See comment)
- Tumor 5 cm in greatest diameter, unencapsulated, has invaded into peritumoral adipose tissue.
- Painted margins of peritumoral adipose tissue negative for tumor.

SYNOPTIC DATA

Specimen Type:	Thoracotomy
Specimen Size:	Greatest dimension: 12 cm Additional dimensions: 12 x 2.1 cm
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 5 cm Additional dimensions: 3 x 2 cm
Histologic Type:	Type B thymoma, B3 (epithelial, atypical, squamoid, well-differentiated thymic carcinoma)
Pathologic Staging:	Stage IIb: Macroscopic capsular invasion
Regional Lymph Nodes:	pN0: No regional lymph node metastasis
Distant Metastasis:	Cannot be assessed
Margins:	Margins uninvolved by tumor Distance of tumor from closest margin: 5 mm
Invasion of Pulmonary Parenchyma:	Absent
Pleural Invasion:	Absent
Vascular (Small/Large Vessel) Invasion:	Absent

[page 2 of 2]
Patient Name:.

MRN:

DOB:

Gender:M

Age:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

COMMENT

The tumor is composed of densely intermixed sheets of epithelial cells and mature lymphocytes. The epithelial cells show irregularly enlarged nuclei with vesicular chromatin and prominent nucleoli. Occasional mitotic figures are noted. These tumor cells demonstrate prominent keratin pearl formation, consistent with squamous differentiation. The tumor has extends irregularly into the adipose tissue but it is uniformly covered by the latter, with painted margins negative for tumor. Most of the lymphocytes are positive for CD1a and CD99 consistent with immature thymocytes. Scattered CD5 positive lymphocytes are also noted by the epithelial tumor cells are negative for CD5. The epithelial tumor cells show strong staining for CK5/6 and high molecular weight cytokeratin. With the majority of lymphocytes being CD1a/CD99 positive and the epithelial tumor cells being CD5 negative, this is more consistent with a type B3 thymoma.

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

Myasthina Gravis

GROSS DESCRIPTION

The specimen is labeled with the patient's name and as "thymus gland and thymoma stitch marks left pleura". It consists of a thymus gland, which is oriented with a suture on the left pleura. The gland measures 12 x 12 x 2.1 cm. It is painted with silver nitrate. The right half of the gland appears unremarkable. A firm tumor, measuring 5 x 3 x 2cm, is identified on sectioning the left half containing the suture. The tumor is variegated tan to red and partly hemorrhagic. Grossly the tumor does not extend to the capsule or pleural surface. Representative sections are submitted.

1A-1C unremarkable right thymus

1D-1H tumor

Status: complete

Page: 2 of 2

Source: NCI Genomic Data Commons file 1d3e7791-1c99-4b90-823d-93ac15a56ae3 (TCGA-XU-AAXZ.543F433F-A26D-4638-8064-8BF6C1BDC165.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).